Somatic mutation profile of tumor specimen 0DWNTK from CCDI case PBCMTM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Small cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 13.3 years (4,865 days).
Specimen 0DWNTK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1296fd8c-e1f0-4e91-9e4c-3f7223ae9560.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNQX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7d65df2-7024-43d1-afac-dbc2f574ef08

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Splice Site 2, Silent 2, 5'UTR 1, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL713999.2 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as rs1228662522; called by muse, mutect2
- GPR62 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs753558984; called by muse, mutect2, varscan2
- LAMC1 | c.2944+1G>A p.X982_splice | Splice Site (SNP) | VAF 172/415 reads (41%) | catalogued as rs1304791097, COSV51155507; called by muse, mutect2, varscan2
- NR3C2 | c.1700C>A p.S567* | Nonsense Mutation (SNP) | VAF 206/430 reads (48%) | catalogued as rs561422296; called by mutect2, varscan2
- AHNAK2 | c.11155G>A p.E3719K | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 26/828 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CACNA2D1 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 140/360 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FHOD3 | c.263A>C p.D88A | Missense Mutation (SNP) | VAF 39/553 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.116); called by muse, mutect2
- GRB14 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 20/536 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- GTPBP6 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 38/748 reads (5%) | SIFT tolerated (0.22); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 23/822 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SBF2 | c.5083C>A p.L1695I | Missense Mutation (SNP) | VAF 262/642 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VWC2L | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 157/349 reads (45%) | called by muse, mutect2, varscan2
- GRIA2 | c.2388C>T p.S796= | Silent (SNP) | VAF 219/599 reads (37%) | catalogued as COSV52383270; called by muse, mutect2, varscan2
- OR52H1 | c.273T>C p.A91= (on ENST00000322653; = p.A97= on NM_001005289.1) | Silent (SNP) | VAF 200/477 reads (42%) | called by muse, mutect2, varscan2
- FAM157A | n.370G>A | RNA (SNP) | VAF 69/290 reads (24%) | called by muse, mutect2, varscan2
- MFSD6 | c.-70del | 5'UTR (DEL) | VAF 50/132 reads (38%) | called by mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, varscan2
